Gene-level copy-number profile of tumor specimen TCGA-29-1693-01A from TCGA case TCGA-29-1693, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.0 years (26,300 days).
Specimen TCGA-29-1693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f2104888-eb63-43d0-afae-a6ebedc57db5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1693-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f519c99-ee1a-4e8b-a027-5dabadcc53b4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4; copy number 2: 16,239; copy number 3: 12,322; copy number 4: 22,895; copy number 5: 2,566; copy number 6: 2,869; copy number 7: 1,736; copy number 8: 53; copy number 9: 109; copy number 10: 684; copy number 11: 334.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1693-01A-01D-0559-01): tumor purity 0.77, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,127 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,149,582–154,155,116, 68 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr1:180,509,380–180,890,279, 4 genes, copy number 9 (within-gene range 6–9): OVAAL, Y_RNA, XPR1, U6.
- chr3:166,835,021–198,222,513, 616 genes, copy number 10 (broad region; genes not listed).
- chr8:122,485,194–122,733,804, 1 gene, copy number 9 (within-gene range 7–9): LINC01151.
- chr8:122,671,291–145,066,685, 438 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
